Somatic mutation profile of tumor specimen TARGET-10-PASHDV-09A (aliquot TARGET-10-PASHDV-09A-01D) from TARGET case TARGET-10-PASHDV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.7 years (4,257 days).
Specimen TARGET-10-PASHDV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1004b0e1-ca75-4a7d-a165-536d426286fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASHDV-14A (Bone Marrow Normal), aliquot TARGET-10-PASHDV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b53ef2db-8e48-491b-9f1e-7e93bc42ba5b

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Intron 2, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.1415G>A p.R472H (on ENST00000357195 / NM_001282237.2; = p.R401H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1231938148, COSV61734054; called by muse, mutect2
- CHD7 | c.3565C>T p.R1189C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71113045; called by muse, mutect2, varscan2
- FOXS1 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV54067505; called by muse, mutect2, varscan2
- HSPA1L | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.167); catalogued as COSV65149304; called by muse, mutect2, varscan2
- JAK1 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61086725; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- LRRN1 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs757427351, COSV60015218; called by muse, mutect2, varscan2
- MAGEC3 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs774885969, COSV53575583; called by muse, mutect2
- MOK | c.591-1G>C p.X197_splice | Splice Site (SNP) | VAF 25/54 reads (46%) | catalogued as COSV51966529; called by muse, mutect2, varscan2
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2, varscan2
- OR10A3 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62459178, COSV62459876; called by muse, mutect2, varscan2
- OSBPL5 | c.1749C>A p.N583K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55144016; called by muse, mutect2, varscan2
- PFAS | c.3871C>T p.H1291Y | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58982103; called by muse, mutect2, varscan2
- PHF6 | c.374+1G>A p.X125_splice | Splice Site (SNP) | VAF 18/21 reads (86%) | catalogued as COSV59701704, COSV59703755; called by muse, mutect2, varscan2
- PRDM6 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as rs1304424685, COSV68337201; called by muse, mutect2, varscan2
- RB1 | c.2626del p.R876Afs*29 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | catalogued as COSV57295580; called by pindel*, varscan2
- SLC12A1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as CM095068, COSV57710832; called by muse, mutect2, varscan2
- STAT5B | c.1883C>G p.T628S | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs774286856, COSV53181461, COSV53185203; called by muse, mutect2, varscan2
- XIRP1 | c.4760G>T p.S1587I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV61139961; called by muse, mutect2, varscan2
- DDX41 | c.937_938insAAGAAGGAGCT p.*313= | Frame Shift Ins (INS) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
- RNF166 | c.637_638insGCATAAGTCTG p.D213Gfs*62 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- ZNF717 | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.42); called by muse, mutect2
- CNTN1 | c.1584G>A p.A528= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs372359836; called by muse, mutect2, varscan2
- DNAH17 | c.11427C>T p.P3809= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs759862644, COSV67762089; called by muse, mutect2, varscan2
- HOXB3 | c.30C>T p.A10= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1381327336, COSV61145688; called by muse, mutect2, varscan2
- MAB21L2 | c.732C>T p.G244= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- CADPS | c.1325+19335G>T | Intron (SNP) | VAF 7/69 reads (10%) | catalogued as rs1171496595; called by muse, mutect2
- ZNF556 | c.-70C>T | 5'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ZNF890P | n.478-50T>C | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
